Somatic mutation profile of tumor specimen TCGA-BT-A0YX-01A (aliquot TCGA-BT-A0YX-01A-11D-A10S-08) from TCGA case TCGA-BT-A0YX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.0 years (25,570 days).
Specimen TCGA-BT-A0YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa093b2-3029-4146-8098-8b731ede6bab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A0YX-10A (Blood Derived Normal), aliquot TCGA-BT-A0YX-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/657a2ee1-582e-4be4-9ce8-694e3aaaea5b

The open-access MAF lists 714 somatic variants for this specimen: 525 protein-altering or splice-affecting, 169 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 469, Silent 169, Nonsense Mutation 38, 5'Flank 8, Intron 7, Splice Site 6, Nonstop Mutation 4, Frame Shift Del 3, Splice Region 3, RNA 2, 5'UTR 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- DMD | c.4222C>T p.Q1408* | Nonsense Mutation (SNP) | VAF 32/144 reads (22%) | catalogued as rs1057524291, COSV63751167; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- INF2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs912928648, CM113753, COSV53035972; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MCOLN1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 29/134 reads (22%) | catalogued as rs797044824, CM003597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6625C>G p.L2209V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774204282, COSV63868849, COSV63879045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- ABCA10 | c.1908C>G p.I636M | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as COSV52223734, COSV52228731; called by muse, mutect2, varscan2
- ABCA8 | c.1835G>C p.R612T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52210099; called by muse, mutect2, varscan2
- ABI2 | c.1443C>G p.I481M (on ENST00000295851 / NM_001375719.1; = p.I443M on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV53695553; called by muse, mutect2, varscan2
- AC008676.3 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56637929; called by muse, mutect2, varscan2
- AC092143.1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59248828; called by muse, varscan2
- ACAN | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs1435969984; called by muse, mutect2
- ADCY2 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV57895297; called by muse, mutect2, varscan2
- ADCY6 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV57170082; called by muse, mutect2, varscan2
- ADGRL1 | c.2248G>A p.E750K (on ENST00000340736 / NM_001008701.3; = p.E745K on NM_014921.5) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs146726289, COSV61566386; called by muse, mutect2, varscan2
- ADGRL2 | c.4045G>C p.D1349H (on ENST00000370717 / NM_001366005.1; = p.D1293H on NM_012302.4) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV54685096; called by muse, mutect2, varscan2
- AFDN | c.3239G>C p.R1080T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60054512; called by muse, mutect2, varscan2
- AGTPBP1 | c.3373G>A p.E1125K (on ENST00000357081 / NM_001330701.2; = p.E1085K on NM_015239.2) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61276393; called by muse, mutect2, varscan2
- AIRE | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV52396635; called by muse, mutect2, varscan2
- ALDH3B1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs757647123, COSV50291338; called by muse, mutect2, varscan2
- ALMS1 | c.3346C>G p.L1116V | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV52520017; called by muse, mutect2, varscan2
- ALPL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs138587317, CM1512156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); catalogued as COSV50828023; called by muse, mutect2, varscan2
- ANKRD26 | c.3613G>C p.E1205Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1564373578, COSV65774159; called by muse, mutect2, varscan2
- ANKRD26 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV65777840; called by muse, mutect2, varscan2
- AP1B1 | c.714G>A p.Q238= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as COSV58022757; called by muse, varscan2
- AP5M1 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as COSV55106672; called by muse, mutect2, varscan2
- ARFGEF1 | c.2751G>C p.Q917H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); catalogued as COSV51615803; called by muse, mutect2, varscan2
- ARHGAP31 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV51797933; called by muse, mutect2, varscan2
- ARID1A | c.5777G>C p.G1926A | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV61387152; called by muse, mutect2, varscan2
- ARID4A | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV62166197; called by muse, mutect2, varscan2
- ARID4B | c.1927-1G>C p.X643_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV51606329; called by muse, mutect2
- ARL2BP | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV54656623; called by muse, mutect2, varscan2
- ARMC4 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs1434873171, COSV59462356; called by muse, mutect2, varscan2
- ARMC9 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV63023100; called by muse, varscan2
- ARMC9 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63023104; called by muse, varscan2
- ASH1L | c.2311G>C p.D771H | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.326); catalogued as COSV64212766; called by muse, mutect2, varscan2
- ASS1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV61690410; called by muse, varscan2
- ASXL2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55461633, COSV55466434; called by muse, mutect2, varscan2
- ATG4D | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as COSV58763577; called by muse, varscan2
- ATG4D | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as rs763771284, COSV58763586; called by muse, varscan2
- ATG4D | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV57265745; called by muse, varscan2
- ATM | c.4367G>A p.G1456D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53762978; called by muse, mutect2, varscan2
- ATP2B4 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as COSV58182944; called by muse, mutect2, varscan2
- ATP2B4 | c.3043G>C p.G1015R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58182969; called by muse, mutect2, varscan2
- ATP5F1A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56361397; called by muse, mutect2, varscan2
- ATP6V0A1 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52877292; called by muse, mutect2, varscan2
- B3GAT3 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53884316; called by muse, mutect2, varscan2
- BAG5 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54572528; called by muse, varscan2
- BCOR | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60698563, COSV60699440; called by muse, mutect2, varscan2
- BCORL1 | c.4697-1G>A p.X1566_splice | Splice Site (SNP) | VAF 86/419 reads (21%) | catalogued as COSV54405049; called by muse, mutect2, varscan2
- BFSP2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs751496741, COSV56587692, COSV56589120; called by muse, mutect2, varscan2
- BHMT2 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV54874485; called by muse, mutect2, varscan2
- BNIP5 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV71325817; called by muse, mutect2, varscan2
- BPI | c.765G>A p.M255I (on ENST00000262865; = p.M251I on NM_001725.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV53403835; called by muse, mutect2
- BPIFA3 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV64926193; called by muse, mutect2, varscan2
- BRAP | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV59538296; called by muse, mutect2, varscan2
- BROX | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV61799337; called by muse, mutect2, varscan2
- BSN | c.3145G>C p.E1049Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56526022; called by muse, mutect2, varscan2
- C12orf50 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53895503, COSV53898279; called by muse, mutect2, varscan2
- C14orf39 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV58784526; called by muse, mutect2, varscan2
- C19orf44 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54171783; called by muse, mutect2, varscan2
- C2 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV54962287; called by muse, mutect2, varscan2
- C2orf16 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV62677891; called by muse, mutect2, varscan2
- CACNA1A | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as rs752824390, COSV64197936; called by muse, mutect2, varscan2
- CAMK4 | c.831C>T p.V277= | Splice Region (SNP) | VAF 16/119 reads (13%) | catalogued as COSV56680755; called by muse, mutect2, varscan2
- CAMKV | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV56557473; called by muse, mutect2, varscan2
- CAMTA2 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs372893979, COSV61837683; called by muse, mutect2, varscan2
- CASZ1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV59740342; called by muse, mutect2, varscan2
- CC2D2A | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1453493262, COSV67505383; called by muse, mutect2, varscan2
- CCDC125 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67288742; called by muse, mutect2, varscan2
- CCDC47 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56724473; called by muse, mutect2, varscan2
- CD109 | c.4283C>T p.S1428L | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV54655651; called by muse, mutect2, varscan2
- CD1E | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV63772615; called by muse, mutect2, varscan2
- CDC42BPA | c.2633C>G p.A878G | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV62018749; called by muse, mutect2
- CDH24 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52981237; called by muse, mutect2, varscan2
- CDK12 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.945); catalogued as rs957118817, COSV70999317, COSV71002323; called by muse, mutect2, varscan2
- CDYL | c.1364C>G p.S455C (on ENST00000328908 / NM_001368125.1; = p.S401C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59361486; called by muse, mutect2, varscan2
- CELSR3 | c.7231C>T p.L2411F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as rs747348369, COSV51137575; called by muse, mutect2, varscan2
- CEP72 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV53796602; called by muse, varscan2
- CHCHD3 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99366670; called by muse, mutect2, varscan2
- CHD1 | c.3809A>G p.Y1270C | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV52344083; called by muse, mutect2, varscan2
- CHD8 | c.5179G>A p.E1727K (on ENST00000646647 / NM_001170629.2; = p.E1448K on NM_020920.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.053); catalogued as COSV63037374; called by muse, mutect2, varscan2
- CHIA | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV58474881, COSV58477113; called by muse, mutect2, varscan2
- CHRNB3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV51497255; called by muse, mutect2, varscan2
- CIT | c.3399G>A p.M1133I | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV55880751; called by muse, mutect2, varscan2
- CLCF1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV56862380; called by muse, mutect2, varscan2
- CLSTN1 | c.1448C>T p.S483F (on ENST00000377298 / NM_001009566.3; = p.S473F on NM_014944.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs542380649, COSV63650593; called by muse, mutect2, varscan2
- CLTCL1 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs553137718, COSV54224919; called by muse, mutect2
- CMSS1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV70435525, COSV70440693; called by muse, mutect2, varscan2
- CMYA5 | c.3179C>T p.S1060L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV71405000; called by muse, mutect2, varscan2
- CNGB1 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs868226949, COSV51906019; called by muse, mutect2, varscan2
- CNNM3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs149301704, COSV59709850; called by muse, varscan2
- CNR1 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.048); catalogued as COSV62986310, COSV62990769; called by muse, mutect2, varscan2
- COL24A1 | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV65312657; called by muse, mutect2, varscan2
- COL28A1 | c.2419G>C p.E807Q | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68084167; called by muse, mutect2, varscan2
- COL4A3 | c.3803G>C p.G1268A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59259324; called by muse, mutect2, varscan2
- COL4A4 | c.4136C>A p.P1379Q | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61635837; called by muse, mutect2, varscan2
- COL6A6 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567427258, COSV62021514; called by muse, mutect2, varscan2
- COL7A1 | c.4235G>A p.G1412E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1474269891, COSV60401980; called by muse, mutect2, varscan2
- COMMD2 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV71946654; called by muse, mutect2
- CPNE1 | c.440G>C p.R147T (on ENST00000352393; = p.R152T on NM_003915.5) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV58294419; called by muse, mutect2, varscan2
- CPT1C | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV54921698; called by muse, mutect2, varscan2
- CRTC3 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV51600077; called by muse, mutect2, varscan2
- CRYBB1 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53234605; called by muse, mutect2, varscan2
- CRYBB1 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99316212; called by muse, mutect2, varscan2
- CUX1 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs374783479; called by muse, mutect2, varscan2
- CX3CR1 | c.295A>T p.N99Y | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV64195080; called by muse, mutect2, varscan2
- CXCL5 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1188667552, COSV56019098; called by muse, mutect2, varscan2
- CXCL8 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs149273289, COSV56641334; called by muse, mutect2, varscan2
- CYB5RL | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55279143; called by muse, mutect2, varscan2
- CYP2C19 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64908297; called by muse, mutect2, varscan2
- D2HGDH | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565397135, COSV58323097; called by muse, mutect2, varscan2
- DCTD | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 32/151 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV63867216; called by muse, mutect2, varscan2
- DCTN5 | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV55616368; called by muse, mutect2, varscan2
- DDIAS | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV61271546; called by muse, mutect2, varscan2
- DDX23 | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57285827; called by muse, mutect2, varscan2
- DDX23 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV57285839; called by muse, mutect2, varscan2
- DDX60 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV67098767; called by muse, mutect2, varscan2
- DEPDC4 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54554243; called by muse, mutect2, varscan2
- DIP2C | c.3034G>C p.E1012Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV55175855; called by muse, mutect2, varscan2
- DLG1 | c.2552G>A p.R851K (on ENST00000419354 / NM_001290983.1; = p.R873K on NM_004087.2) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV58389720; called by muse, mutect2
- DLG3 | c.2095G>A p.D699N (on ENST00000374360 / NM_021120.4; = p.D394N on NM_020730.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.898); catalogued as COSV52086402; called by muse, mutect2, varscan2
- DLL4 | c.1908G>C p.K636N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51070060; called by muse, mutect2, varscan2
- DLX2 | c.930C>G p.H310Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV52232772; called by muse, mutect2, varscan2
- DNAH8 | c.5971C>G p.L1991V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV59475247; called by muse, mutect2, varscan2
- DNAH8 | c.9254C>T p.S3085F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59475285; called by muse, mutect2, varscan2
- DNAH9 | c.13146G>C p.K4382N | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52372349; called by muse, mutect2, varscan2
- DPY19L2 | c.2120G>C p.R707T | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs760400365, COSV61045362; called by muse, mutect2, varscan2
- DRP2 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1322622414, COSV65811599; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1361G>C p.R454T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.159); catalogued as COSV50052996; called by muse, mutect2, varscan2
- EARS2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV71942953; called by muse, mutect2, varscan2
- EIF3A | c.2623G>C p.E875Q | Missense Mutation (SNP) | VAF 90/351 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV64962993; called by muse, mutect2, varscan2
- EIF3L | c.1206G>C p.Q402H | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67740016; called by muse, mutect2, varscan2
- EPRS1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV65101240; called by muse, mutect2, varscan2
- ERBB2 | c.3730G>C p.E1244Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV54080732; called by muse, mutect2, varscan2
- ERN2 | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV55624046; called by muse, mutect2, varscan2
- EXOSC5 | c.650C>G p.S217W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754247072, COSV55370676, COSV55372173; called by muse, mutect2, varscan2
- EXTL3 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs1432191459, COSV55040119, COSV55040440; called by muse, mutect2, varscan2
- F8 | c.4201C>G p.Q1401E | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as CM061753, COSV64269314, COSV64278603; called by muse, mutect2, varscan2
- FAM155A | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as rs1315765909, COSV65554804, COSV65583515; called by muse, mutect2, varscan2
- FAM171B | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as COSV59007819; called by muse, mutect2, varscan2
- FAM171B | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59007831; called by muse, mutect2, varscan2
- FAM217B | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV62565007; called by muse, mutect2, varscan2
- FAM83H | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV62029434; called by muse, mutect2, varscan2
- FAM89B | c.457G>A p.D153N (on ENST00000530349 / NM_001098785.2; = p.D140N on NM_152832.3) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs547806714, COSV57080074; called by muse, varscan2
- FANCD2 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV55045270; called by muse, mutect2, varscan2
- FANCD2 | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 74/345 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.228); catalogued as COSV55045281; called by muse, mutect2, varscan2
- FANCM | c.5176C>G p.P1726A | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV57505594; called by muse, mutect2, varscan2
- FAT4 | c.4322C>T p.S1441L | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV67897809; called by muse, mutect2, varscan2
- FAT4 | c.9193G>C p.D3065H | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58704400; called by muse, mutect2, varscan2
- FBXW12 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV56482960; called by muse, mutect2, varscan2
- FBXW7 | c.1411del p.E471Kfs*27 (on ENST00000281708 / NM_001349798.2; = p.E391Kfs*27 on NM_018315.5) | Frame Shift Del (DEL) | VAF 46/238 reads (19%) | catalogued as COSV55901493, COSV55945979, COSV55948852; called by pindel, varscan2
- FBXW7 | c.1277C>T p.S426L (on ENST00000281708 / NM_001349798.2; = p.S346L on NM_018315.5) | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1316840275, COSV104381567, COSV55917417, COSV55930051; called by muse, varscan2
- FBXW9 | c.612C>G p.I204M (on ENST00000587955; = p.I214M on NM_032301.3) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100790381, COSV63509837; called by muse, mutect2
- FCRL5 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs1168657569, COSV62519323; called by muse, mutect2, varscan2
- FER | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV55302923; called by muse, mutect2, varscan2
- FER1L6 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as COSV67552370; called by muse, mutect2, varscan2
- FGD4 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs749693316, COSV56788601; called by muse, mutect2, varscan2
- FGF8 | c.378C>G p.I126M (on ENST00000344255 / NM_033164.4; = p.I108M on NM_006119.6) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV60143582; called by muse, mutect2, varscan2
- FLG2 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV66171979, COSV66172265; called by muse, mutect2, varscan2
- FLVCR1 | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV63134454; called by muse, mutect2, varscan2
- FNBP4 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as COSV55451607; called by muse, varscan2
- FNBP4 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV55451618; called by muse, varscan2
- FOSL2 | c.35C>G p.S12W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53105440; called by muse, mutect2, varscan2
- FOXA2 | c.522G>C p.Q174H (on ENST00000377115 / NM_153675.3; = p.Q180H on NM_021784.5) | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV65797012; called by muse, mutect2, varscan2
- FURIN | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1049334257, COSV51579181; called by muse, mutect2, varscan2
- FUS | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as COSV99568928; called by muse, mutect2, varscan2
- GABRA4 | c.1096C>G p.P366A | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV51933979; called by muse, mutect2, varscan2
- GABRG1 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV54958349, COSV54960657; called by muse, mutect2, varscan2
- GALNT5 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52040570, COSV99375446; called by muse, mutect2, varscan2
- GAPVD1 | c.3268G>A p.E1090K (on ENST00000394104; = p.E1099K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs752026573, COSV52926780; called by muse, mutect2, varscan2
- GBE1 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV70102326; called by muse, mutect2, varscan2
- GHDC | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56989599; called by muse, mutect2, varscan2
- GLI3 | c.4483G>A p.D1495N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs745631926, COSV67894060; called by muse, mutect2, varscan2
- GLIS2 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.431); catalogued as COSV52111780; called by muse, mutect2, varscan2
- GLYATL1 | c.677C>T p.S226F (on ENST00000317391 / NM_001354699.1; = p.S257F on NM_080661.4) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55611024; called by muse, mutect2, varscan2
- GOLGB1 | c.8691G>C p.L2897F | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61470103; called by muse, mutect2, varscan2
- GOLGB1 | c.2254C>A p.Q752K | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV61470110; called by muse, mutect2, varscan2
- GPBP1 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV53313992; called by muse, mutect2, varscan2
- GPC5 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100995621; called by muse, mutect2, varscan2
- GPR17 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55756832; called by muse, varscan2
- GRIA4 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV56915849, COSV99232456; called by muse, mutect2, varscan2
- GRIK2 | c.1149G>C p.L383F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as COSV59764491; called by muse, mutect2
- GTF2I | c.2579C>T p.S860L (on ENST00000573035 / NM_032999.4; = p.S819L on NM_001518.5) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100259957; called by muse, mutect2, varscan2
- HAUS3 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54723880; called by muse, mutect2, varscan2
- HCN4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.066); catalogued as COSV56081499; called by muse, varscan2
- HDX | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV52982070, COSV52983131; called by muse, mutect2, varscan2
- HID1 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV60914795; called by muse, mutect2, varscan2
- HK2 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV51878239, COSV51878851; called by muse, mutect2, varscan2
- HMCES | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.024); catalogued as COSV67300900; called by muse, mutect2, varscan2
- HMCES | c.855G>C p.Q285H | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV67300902; called by muse, varscan2
- HMCES | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs757343424, COSV67300903; called by muse, varscan2
- HMCN1 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54934240; called by muse, mutect2, varscan2
- HOXA5 | c.176C>G p.S59W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV56074582; called by mutect2, varscan2
- HPGDS | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs760667106, COSV54775735; called by muse, varscan2
- HPSE | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as rs1167694088, COSV60986125; called by muse, mutect2, varscan2
- HPSE | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60988380, COSV60988481; called by muse, varscan2
- IFRD1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50045107, COSV99133656; called by muse, mutect2, varscan2
- IGF2 | c.649C>G p.L217V (on ENST00000434045 / NM_001127598.3; = p.L161V on NM_000612.6) | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV56101295; called by muse, mutect2, varscan2
- IL1RL1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV52119734; called by muse, mutect2, varscan2
- INTS14 | c.1483G>C p.E495Q (on ENST00000313182 / NM_001366360.2; = p.E416Q on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV56012534; called by muse, mutect2, varscan2
- ISM1 | c.203C>A p.P68Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52607536; called by muse, mutect2, varscan2
- ITGB3 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV71385136; called by muse, mutect2, varscan2
- ITLN2 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs755418453, COSV63538160; called by muse, mutect2, varscan2
- ITPR3 | c.7759G>C p.E2587Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65268876; called by muse, mutect2, varscan2
- JAG1 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as CD030144; called by muse, varscan2
- JAK1 | c.2939A>T p.Q980L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61095635; called by muse, mutect2, varscan2
- KALRN | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as COSV53764262, COSV53777751; called by muse, mutect2, varscan2
- KALRN | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV53763675; called by muse, mutect2, varscan2
- KAT2B | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55433662; called by muse, mutect2, varscan2
- KBTBD6 | c.1632G>C p.W544C | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65271894; called by muse, varscan2
- KBTBD6 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs756607623, COSV65271899; called by muse, varscan2
- KBTBD6 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65271905; called by muse, mutect2, varscan2
- KCNJ14 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.105); catalogued as COSV60738789; called by muse, mutect2, varscan2
- KCNK2 | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs766967584, COSV101222263, COSV67204276, COSV67204289; called by muse, mutect2, varscan2
- KCNN2 | c.1515G>C p.K505N (on ENST00000264773; = p.K717N on NM_021614.4) | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV53297466; called by muse, mutect2, varscan2
- KCNQ5 | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59678955; called by muse, varscan2
- KCNS2 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54640807; called by muse, varscan2
- KIAA0100 | c.5690G>A p.R1897Q | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200543420, COSV56382590; called by muse, mutect2, varscan2
- KIF11 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV53273494; called by muse, mutect2, varscan2
- KIF15 | c.3841G>C p.E1281Q | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.731); catalogued as rs77808243, COSV58164299; called by muse, mutect2, varscan2
- KIF1C | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 39/172 reads (23%) | catalogued as rs1186425348; called by muse, mutect2, varscan2
- KIRREL2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52879543; called by muse, mutect2, varscan2
- KIRREL2 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52879561; called by muse, mutect2, varscan2
- KLHL2 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56982011; called by muse, mutect2, varscan2
- KLHL40 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs757566258, COSV55136892; called by muse, mutect2, varscan2
- KMT2D | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV56429213; called by muse, mutect2, varscan2
- KMT5A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV57864457; called by muse, mutect2, varscan2
- KNL1 | c.5655G>C p.L1885F (on ENST00000346991 / NM_170589.5; = p.L1859F on NM_144508.5) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61159566; called by muse, varscan2
- KPNA1 | c.114G>C p.Q38H | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV60271198; called by muse, mutect2, varscan2
- KPNA3 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV55506782; called by muse, mutect2, varscan2
- KRT31 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1298636803, COSV52437855; called by muse, mutect2, varscan2
- KRTAP13-2 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV67762260; called by muse, mutect2, varscan2
- KYAT3 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV53105016; called by muse, mutect2, varscan2
- L3MBTL2 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53435359; called by muse, mutect2, varscan2
- LAMA5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs1240568062, COSV53370539; called by muse, mutect2, varscan2
- LAMC3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.075); catalogued as COSV63094839; called by muse, mutect2, varscan2
- LAMP2 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52354802; called by muse, mutect2, varscan2
- LCN2 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV52981742; called by muse, mutect2, varscan2
- LCOR | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV63632191; called by muse, mutect2, varscan2
- LFNG | c.933C>G p.F311L (on ENST00000222725 / NM_001040167.2; = p.F182L on NM_002304.2) | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV56070813; called by muse, varscan2
- LRIT2 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.1); catalogued as COSV64519762; called by muse, mutect2, varscan2
- LRRC8B | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV58376789; called by muse, mutect2, varscan2
- LRRK2 | c.6999G>C p.Q2333H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.45); catalogued as COSV54167802; called by muse, mutect2, varscan2
- MACF1 | c.4991G>C p.G1664A | Missense Mutation (SNP) | VAF 32/158 reads (20%) | catalogued as COSV57140267; called by muse, mutect2, varscan2
- MAGI2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as rs777063252, COSV62645997; called by muse, mutect2, varscan2
- MAN2B2 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs760614382, COSV53456220; called by muse, mutect2, varscan2
- MAP2 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV52305156; called by muse, mutect2, varscan2
- MAP4K2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV53647593; called by muse, mutect2, varscan2
- MAPK8IP3 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV50189368; called by muse, mutect2, varscan2
- MARCHF11 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as COSV60133758; called by muse, mutect2, varscan2
- MDGA1 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV51800844; called by muse, mutect2, varscan2
- ME3 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62774686; called by muse, mutect2, varscan2
- MECOM | c.2711A>T p.E904V (on ENST00000468789 / NM_001105078.4; = p.E1092V on NM_004991.4) | Missense Mutation (SNP) | VAF 173/425 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV52972747; called by muse, mutect2, varscan2
- MECOM | c.2710G>A p.E904K (on ENST00000468789 / NM_001105078.4; = p.E1092K on NM_004991.4) | Missense Mutation (SNP) | VAF 177/430 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as rs1458909612, COSV52972789; called by muse, mutect2, varscan2
- MED13 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV67266542; called by muse, mutect2, varscan2
- METTL4 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV60604667; called by muse, mutect2, varscan2
- MINDY4 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV54677872; called by muse, mutect2, varscan2
- MIP | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57513130, COSV57514644; called by muse, mutect2, varscan2
- MLX | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as rs775956555, COSV53818699; called by muse, mutect2, varscan2
- MOGS | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51971393; called by muse, mutect2, varscan2
- MOV10L1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.133); catalogued as COSV53178026; called by muse, mutect2, varscan2
- MPV17L2 | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55853682; called by muse, mutect2, varscan2
- MRPL22 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV54559273; called by muse, mutect2, varscan2
- MRPL53 | c.338G>T p.*113Lext*14 | Nonstop Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as rs779678862, COSV99251992; called by muse, varscan2
- MRPL57 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV53436700; called by muse, mutect2, varscan2
- MTERF4 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs753490758, COSV54090838; called by muse, mutect2, varscan2
- MUC21 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV66221978; called by muse, varscan2
- MYBPC1 | c.739G>C p.E247Q (on ENST00000550270 / NM_206820.2; = p.E272Q on NM_002465.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV62256966; called by muse, mutect2, varscan2
- MYOF | c.2317_2319del p.P773del | In Frame Del (DEL) | VAF 15/117 reads (13%) | catalogued as COSV63709695; called by mutect2, pindel, varscan2
- MYT1L | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV67730486; called by muse, mutect2
- NAA16 | c.1883G>C p.R628T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs777680792, COSV65129592; called by muse, mutect2, varscan2
- NAV3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | catalogued as rs1301351243; called by muse, mutect2, varscan2
- NBEA | c.8159G>A p.W2720* | Nonsense Mutation (SNP) | VAF 71/322 reads (22%) | catalogued as COSV59829009; called by muse, mutect2, varscan2
- NCAM2 | c.2500G>C p.D834H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53055743, COSV53099064; called by muse, mutect2, varscan2
- NCAPD3 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV73258721; called by muse, mutect2, varscan2
- NDST3 | c.2352G>C p.Q784H | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56627529; called by muse, mutect2, varscan2
- NEDD4 | c.3364G>A p.D1122N (on ENST00000508342 / NM_001284338.1; = p.D703N on NM_006154.4) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59065939; called by muse, mutect2, varscan2
- NEUROD1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54548711, COSV54550867; called by muse, mutect2, varscan2
- NKTR | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51774728; called by muse, mutect2, varscan2
- NLRP10 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1313490095, COSV60782242; called by muse, mutect2, varscan2
- NME9 | c.415G>A p.E139K (on ENST00000333911 / NM_001349024.2; = p.E78K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV58622165; called by muse, mutect2, varscan2
- NOL4 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as COSV52359407; called by muse, mutect2, varscan2
- NOL9 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.07); catalogued as COSV104427645, COSV66626850; called by muse, mutect2, varscan2
- NOS1 | c.2757G>C p.M919I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.292); catalogued as COSV57620062; called by muse, mutect2, varscan2
- NOTCH2 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV56693318, COSV56703222; called by muse, mutect2, varscan2
- NPDC1 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV65391194; called by muse, mutect2, varscan2
- NR4A2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV59895380; called by muse, mutect2, varscan2
- NUP188 | c.1843G>A p.V615I | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV65364439; called by muse, mutect2, varscan2
- OGDH | c.2915G>C p.R972T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056019; called by muse, mutect2, varscan2
- OPA1 | c.865G>A p.E289K (on ENST00000361510 / NM_130837.3; = p.E234K on NM_015560.3) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1319065221, COSV62482948; called by muse, mutect2, varscan2
- OPA1 | c.1837G>C p.E613Q (on ENST00000361510 / NM_130837.3; = p.E558Q on NM_015560.3) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV62481706; called by muse, mutect2
- OR10A5 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV55055451; called by muse, mutect2, varscan2
- OR10K2 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV100149387, COSV59222515; called by muse, mutect2, varscan2
- OR5L2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 108/425 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV101004351, COSV65724976; called by muse, mutect2, varscan2
- OR7A5 | c.453G>C p.M151I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as COSV59235369; called by muse, mutect2, varscan2
- OTOP2 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201869769; called by muse, mutect2, varscan2
- PA2G4 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV57570256; called by muse, mutect2, varscan2
- PACS1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57699576; called by muse, mutect2, varscan2
- PAFAH2 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV65340129; called by muse, mutect2, varscan2
- PARP14 | c.5368C>G p.Q1790E | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV71735457; called by muse, mutect2, varscan2
- PARP9 | c.1969C>G p.Q657E | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100831180, COSV64451680; called by muse, mutect2, varscan2
- PAXIP1 | c.3094G>A p.D1032N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66897973, COSV66898890; called by muse, mutect2, varscan2
- PCDH7 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337676; called by muse, mutect2
- PCDHA7 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs1554134461, COSV65346870; called by muse, mutect2
- PCDHA9 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as rs1554142470; called by muse, mutect2
- PCDHB14 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV53386204; called by muse, mutect2, varscan2
- PCDHB7 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.384); catalogued as rs782231992, COSV50789101, COSV50807602; called by muse, mutect2, varscan2
- PCDHGA7 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53992535; called by muse, mutect2, varscan2
- PCDHGA9 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53926301; called by muse, mutect2, varscan2
- PCDHGC5 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191201177, COSV52746883; called by muse, mutect2, varscan2
- PCLO | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as COSV61636675; called by muse, mutect2
- PDCD10 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67103086, COSV67103151; called by muse, mutect2, varscan2
- PDE1A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs775065809, COSV59521241; called by muse, mutect2, varscan2
- PDIA5 | c.1079A>T p.N360I | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs1396139181, COSV60251969; called by muse, mutect2, varscan2
- PHYHIPL | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53254788; called by muse, mutect2, varscan2
- PI16 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV65448615; called by muse, mutect2, varscan2
- PIDD1 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV61706771; called by muse, mutect2, varscan2
- PIK3CB | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs143122477, COSV56686785; called by muse, mutect2, varscan2
- PIK3R4 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63243568; called by muse, mutect2, varscan2
- PIWIL4 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54411895; called by muse, mutect2, varscan2
- PKLR | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV61362405, COSV61362446; called by muse, mutect2, varscan2
- PLCH1 | c.4180C>G p.Q1394E (on ENST00000340059 / NM_001130960.2; = p.Q1386E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); catalogued as COSV58208511; called by muse, mutect2, varscan2
- PLEKHA4 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV54365236, COSV54365574; called by muse, mutect2, varscan2
- PLEKHN1 | c.1960G>C p.E654Q (on ENST00000379409; = p.E602Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV58023542; called by muse, mutect2, varscan2
- PMPCB | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV50787735; called by muse, mutect2, varscan2
- PNMA1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1015285646, COSV54098218; called by muse, mutect2, varscan2
- PNMA1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs928506842, COSV54098223; called by muse, mutect2, varscan2
- POLD2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56259025, COSV56260736; called by muse, mutect2, varscan2
- POLG2 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as COSV56750926; called by muse, mutect2, varscan2
- PPP1CA | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV56704888; called by muse, mutect2, varscan2
- PPP1R12B | c.1542-1G>A p.X514_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as COSV61122793; called by muse, mutect2, varscan2
- PPP1R15B | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV65816457; called by muse, mutect2, varscan2
- PPP1R15B | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV65816461; called by muse, mutect2, varscan2
- PPP1R17 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.223); catalogued as rs1356302730, COSV59612335; called by muse, varscan2
- PPP1R9A | c.3088C>G p.L1030V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56907909; called by muse, mutect2, varscan2
- PPP2R1B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs199554698; called by muse, mutect2, varscan2
- PRF1 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV64615752; called by muse, mutect2, varscan2
- PRG2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as COSV61294053; called by muse, mutect2, varscan2
- PROM2 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV58300360; called by muse, mutect2, varscan2
- PRRC2C | c.3096G>C p.Q1032H (on ENST00000367742; = p.Q1030H on NM_015172.4) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as rs766536643, COSV58911820; called by muse, mutect2, varscan2
- PRSS48 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV71614161; called by muse, mutect2, varscan2
- PSEN1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56196534; called by muse, mutect2, varscan2
- PSG3 | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs141177217; called by muse, mutect2, varscan2
- PSMA6 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV54837723, COSV54838972; called by muse, mutect2, varscan2
- PSME4 | c.2421-1G>C p.X807_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV101122577, COSV66367194; called by mutect2, varscan2
- PTCH1 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV59467695, COSV59487844, COSV59490927; called by muse, mutect2, varscan2
- PTGER4 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56722042; called by muse, mutect2, varscan2
- PTN | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV61969002; called by muse, mutect2, varscan2
- PTPDC1 | c.83G>C p.G28A (on ENST00000375360 / NM_177995.3; = p.R80T on NM_152422.4) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV56626004; called by mutect2, varscan2
- PTPRU | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV60534976, COSV60535271; called by muse, mutect2, varscan2
- PYHIN1 | c.453G>C p.R151S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV63722231, COSV63723825; called by mutect2, varscan2
- RAB11FIP4 | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57932355; called by muse, mutect2, varscan2
- RAB40B | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53918030; called by muse, mutect2, varscan2
- RAB5A | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56085802; called by muse, mutect2
- RBM15 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV63924338; called by muse, mutect2, varscan2
- RERE | c.4270C>G p.P1424A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61949163; called by muse, mutect2, varscan2
- RFC4 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV56218395; called by muse, mutect2, varscan2
- RFC4 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56218405; called by muse, mutect2, varscan2
- RGS2 | c.357C>G p.F119L | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52459691; called by muse, mutect2, varscan2
- RIMS1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV53438714, COSV53440385; called by muse, mutect2, varscan2
- RIMS2 | c.2818C>G p.H940D (on ENST00000666250 / NM_001348490.2; = p.H748D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV51705579, COSV51717316; called by muse, mutect2, varscan2
- RNF39 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54994253; called by muse, mutect2, varscan2
- ROCK1 | c.2867G>C p.R956T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV67698929; called by muse, mutect2, varscan2
- ROS1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1298952570, COSV63853172; called by muse, mutect2, varscan2
- RP1L1 | c.5416C>G p.Q1806E | Missense Mutation (SNP) | VAF 92/425 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV66757833, COSV66759350; called by muse, mutect2, varscan2
- RSL1D1 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV63078391; called by muse, mutect2, varscan2
- RTKN2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV59524198; called by muse, mutect2, varscan2
- RYR2 | c.4841G>A p.R1614H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); catalogued as rs746943081, COSV63679337, COSV63709094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53855490; called by muse, mutect2, varscan2
- SCAI | c.1141G>A p.E381K (on ENST00000336505 / NM_001144877.3; = p.E404K on NM_173690.5) | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV60617119; called by muse, mutect2, varscan2
- SCN11A | c.3220-1G>C p.X1074_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56576846; called by muse, mutect2, varscan2
- SCN3A | c.3963G>A p.M1321I | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV51821716; called by muse, mutect2, varscan2
- SEL1L | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 162/786 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60922236; called by muse, mutect2, varscan2
- SEL1L2 | c.1116C>G p.I372M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53156800; called by muse, mutect2, varscan2
- SERTAD4 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs764227429, COSV65399679; called by muse, mutect2, varscan2
- SEZ6L2 | c.2621C>T p.S874F (on ENST00000308713 / NM_001114099.3; = p.S817F on NM_012410.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as rs781464322, COSV58102959; called by muse, mutect2, varscan2
- SHROOM1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60582276; called by muse, mutect2, varscan2
- SLC10A2 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145541774; called by muse, mutect2, varscan2
- SLC16A1 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV63709556, COSV63710042; called by muse, mutect2, varscan2
- SLC38A10 | c.1886G>T p.G629V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs750774319, COSV55848724; called by muse, mutect2, varscan2
- SLC44A5 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63758215; called by muse, mutect2, varscan2
- SLC6A16 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV60029817; called by muse, mutect2, varscan2
- SLC9A8 | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64290813; called by muse, mutect2, varscan2
- SLCO4C1 | c.1134G>C p.L378F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60519523; called by muse, mutect2, varscan2
- SLCO5A1 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52655145; called by muse, mutect2, varscan2
- SLX4 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as COSV53567812; called by muse, mutect2, varscan2
- SMAD2 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50992847; called by muse, mutect2, varscan2
- SMAD4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61692299, COSV61693477; called by muse, mutect2, varscan2
- SMPDL3A | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143627205, COSV63755787; called by muse, mutect2, varscan2
- SNX25 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV53017911; called by muse, mutect2, varscan2
- SOS1 | c.3880C>G p.P1294A | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67677352; called by muse, mutect2, varscan2
- SPG7 | c.988-4C>G | Splice Region (SNP) | VAF 8/78 reads (10%) | catalogued as COSV51953959; called by muse, varscan2
- SPHK2 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV55336459, COSV55341544; called by muse, mutect2, varscan2
- SPRR2F | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 81/381 reads (21%) | PolyPhen benign (0); catalogued as rs533901980, COSV64207543; called by muse, mutect2, varscan2
- SPTAN1 | c.7185G>A p.M2395I | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63989469; called by muse, mutect2, varscan2
- SRSF1 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51966300; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 18/103 reads (17%) | PolyPhen benign (0.076); catalogued as COSV52536474; called by muse, mutect2, varscan2
- STKLD1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.183); catalogued as rs1554777705, COSV64241592; called by muse, mutect2, varscan2
- STX8 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV60487694, COSV60494783; called by muse, mutect2, varscan2
- SVEP1 | c.3039C>G p.F1013L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57045589; called by muse, mutect2, varscan2
- SVEP1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1442818373, COSV57047779; called by muse, mutect2
- SYNE1 | c.25287G>C p.L8429F (on ENST00000367255 / NM_182961.4; = p.L8381F on NM_033071.3) | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV54942253, COSV55079614; called by muse, mutect2, varscan2
- SZT2 | c.6895C>G p.L2299V (on ENST00000634258 / NM_001365999.1; = p.L2242V on NM_015284.4) | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs762982299, COSV65173735; called by muse, mutect2, varscan2
- TAC1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs917447235, COSV59988115; called by muse, mutect2, varscan2
- TAF7L | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV61257873; called by muse, mutect2, varscan2
- TBC1D25 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65124554; called by muse, mutect2, varscan2
- TBC1D5 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV53768551; called by muse, mutect2, varscan2
- TBXT | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV51616035, COSV51619673, COSV99752603; called by muse, mutect2, varscan2
- TDRD1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52595125; called by muse, mutect2, varscan2
- TENM2 | c.2363G>A p.R788Q (on ENST00000518659 / NM_001122679.2; = p.R556Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs200354006; called by muse, mutect2, varscan2
- TEX2 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555631976, COSV51984966; called by muse, mutect2, varscan2
- TGFBR3 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53030353; called by muse, mutect2, varscan2
- TIMM44 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV54494270; called by muse, mutect2, varscan2
- TK1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV56746536; called by muse, mutect2
- TM6SF1 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as rs780558833, COSV51945964, COSV51946706; called by muse, mutect2
- TMOD2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as COSV51046715; called by muse, mutect2, varscan2
- TMPRSS11F | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100678856, COSV62468928; called by muse, mutect2, varscan2
- TNFSF11 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53479423; called by muse, mutect2, varscan2
- TNKS2 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65416721; called by muse, mutect2, varscan2
- TNS1 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50755958; called by muse, mutect2, varscan2
- TOP1 | c.345A>T p.Q115H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV63695781; called by muse, mutect2, varscan2
- TOR1AIP1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as rs761950048, COSV54871531; called by muse, mutect2, varscan2
- TP53I3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1264776571, COSV51981745; called by muse, mutect2, varscan2
- TPM2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV61407541; called by muse, mutect2, varscan2
- TPR | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66604302; called by muse, mutect2, varscan2
- TPRG1 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV61468168; called by muse, mutect2, varscan2
- TRIM42 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV53886325; called by muse, mutect2, varscan2
- TRIM59 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 21/165 reads (13%) | catalogued as COSV100557496; called by muse, mutect2, varscan2
- TRUB1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs143607039; called by muse, mutect2, varscan2
- TTLL5 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs771654537, COSV54042722; called by muse, mutect2, varscan2
- TTN | c.47753C>T p.S15918L (on ENST00000591111; = p.S8494L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen probably damaging (0.996); catalogued as COSV60293700; called by muse, mutect2, varscan2
- TTN | c.23596G>C p.E7866Q (on ENST00000591111; = p.E6939Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | PolyPhen possibly damaging (0.649); catalogued as rs201365398; called by muse, mutect2, varscan2
- TTN | c.14956G>A p.A4986T (on ENST00000591111; = p.A4059T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | PolyPhen benign (0.009); catalogued as rs72648934, COSV60187804; called by muse, mutect2, varscan2
- TULP4 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65572867; called by muse, mutect2, varscan2
- UBP1 | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52147500; called by muse, mutect2, varscan2
- UCKL1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62403656; called by muse, mutect2, varscan2
- ULK2 | c.2240G>C p.R747T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV64447967; called by muse, mutect2, varscan2
- UNC45B | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771256591, COSV52099951; called by muse, mutect2, varscan2
- UPF2 | c.2893G>C p.D965H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV62663218; called by muse, mutect2, varscan2
- USP28 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as rs1342151619; called by muse, mutect2, varscan2
- USP38 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.487); catalogued as rs199547940, COSV61026651, COSV61027225; called by muse, mutect2, varscan2
- USP42 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60363877; called by muse, mutect2, varscan2
- USP47 | c.1251G>A p.M417I (on ENST00000399455 / NM_001372095.1; = p.M329I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1465872144, COSV60467367; called by muse, mutect2, varscan2
- USP9X | c.6248A>T p.N2083I | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV61074240; called by muse, mutect2, varscan2
- UTP20 | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1270999205, COSV55384187; called by muse, mutect2, varscan2
- UTP23 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1418159263, COSV52671433; called by muse, mutect2, varscan2
- VAC14 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV55757081; called by muse, mutect2, varscan2
- VIRMA | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV52590310; called by muse, mutect2, varscan2
- WASL | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV56135779; called by muse, varscan2
- WDR17 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV54581917, COSV54584055; called by muse, mutect2
- WDR64 | c.3173G>C p.R1058T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV63798259, COSV63799752; called by muse, mutect2, varscan2
- WNK1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60043515; called by muse, mutect2, varscan2
- WWC2 | c.3403G>C p.E1135Q | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV67861316; called by muse, mutect2, varscan2
- XPR1 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62559931; called by muse, varscan2
- YARS1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as rs147005844, COSV65113391; called by muse, mutect2, varscan2
- YTHDF2 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65723868, COSV65724014; called by muse, mutect2, varscan2
- ZBED8 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.714); catalogued as COSV68824992; called by muse, mutect2, varscan2
- ZBTB37 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); catalogued as COSV62931377, COSV62934340; called by muse, mutect2, varscan2
- ZFP57 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as COSV65306864; called by muse, mutect2, varscan2
- ZFYVE27 | c.1185G>C p.Q395H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61747263; called by muse, mutect2
- ZIC3 | c.966C>G p.H322Q | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV54976436; called by muse, mutect2, varscan2
- ZMYM2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV67037029; called by muse, varscan2
- ZMYM2 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV104430639, COSV67037034; called by muse, varscan2
- ZNF227 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV57313492; called by muse, mutect2, varscan2
- ZNF263 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 49/227 reads (22%) | catalogued as COSV99526868; called by muse, mutect2, varscan2
- ZNF330 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53708339; called by muse, mutect2, varscan2
- ZNF335 | c.4021G>A p.D1341N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs200346507; called by muse, mutect2, varscan2
- ZNF354C | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV59609589; called by muse, mutect2, varscan2
- ZNF395 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV60430168; called by muse, mutect2, varscan2
- ZNF461 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV64454971; called by muse, mutect2, varscan2
- ZNF462 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV52949360; called by muse, mutect2, varscan2
- ZNF507 | c.620G>T p.R207I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV61333056; called by muse, mutect2, varscan2
- ZNF562 | c.265G>A p.E89K (on ENST00000453372 / NM_001130032.2; = p.E17K on NM_017656.4) | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV53335145; called by muse, mutect2, varscan2
- ZNF620 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58820871; called by muse, mutect2, varscan2
- ZNF655 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as COSV53159886; called by muse, varscan2
- ZNF655 | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV53158887, COSV53159927; called by muse, mutect2, varscan2
- ZSCAN30 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV54350399, COSV54352461; called by muse, mutect2, varscan2
- AGAP4 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- ATF7 | c.1286C>G p.S429* (on ENST00000548446 / NM_001366555.2; = p.S418* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2
- BAG5 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 42/172 reads (24%) | called by muse, varscan2
- BNC2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- BRD7 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CCDC18 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 46/194 reads (24%) | called by muse, mutect2, varscan2
- CCL3 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CEP170 | c.2354C>G p.S785* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | called by muse, varscan2
- CGN | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- CHKB | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- CILP2 | c.443C>G p.S148W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- COA8 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- COL15A1 | c.3626C>G p.S1209* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- CORO6 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- CYB561D2 | c.668G>C p.*223Sext*15 | Nonstop Mutation (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- DTX3 | c.483G>C p.E161D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.03); called by muse, mutect2
- DUSP14 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- ELF1 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 63/263 reads (24%) | called by muse, mutect2, varscan2
- FLCN | c.1739G>C p.*580Sext*135 | Nonstop Mutation (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- GGN | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, varscan2
- GOLIM4 | c.518-1G>C p.X173_splice | Splice Site (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2
- HEATR6 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.056); called by muse, mutect2
- HECTD1 | c.7253C>G p.S2418* | Nonsense Mutation (SNP) | VAF 35/126 reads (28%) | called by muse, mutect2, varscan2
- HLX | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- HNRNPUL1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOOK1 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF5 | c.627del p.K209Nfs*24 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- MAGEA3 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MUC5B | c.266_281del p.D89Afs*29 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- PANX3 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 53/266 reads (20%) | called by muse, mutect2, varscan2
- RARA | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- RNASE10 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- RPL10 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATS1 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- TRAF2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.217); called by muse, mutect2
- TRDV3 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- VPS13D | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | called by muse, varscan2
- VRTN | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- YAP1 | c.1513T>C p.*505Qext*6 (on ENST00000282441 / NM_001130145.3; = p.*451Qext*6 on NM_006106.5) | Nonstop Mutation (SNP) | VAF 58/188 reads (31%) | called by muse, mutect2, varscan2
- ZDHHC1 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.018); called by muse, mutect2
- ZNF17 | c.1616C>G p.S539* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- ZNF222 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ZNF70 | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 51/232 reads (22%) | called by muse, mutect2, varscan2
- ABHD18 | c.558G>A p.E186= (on ENST00000398965 / NM_001039717.2; = p.E59= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1372878077, COSV66294697; called by muse, mutect2, varscan2
- ACTL7A | c.1095G>C p.T365= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV61777203; called by muse, mutect2, varscan2
- ADAMTS4 | c.1014C>T p.V338= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV63487470, COSV63488559; called by muse, varscan2
- ADGRD1 | c.1386G>A p.L462= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV55455056; called by muse, mutect2
- ADGRV1 | c.18747G>A p.L6249= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV67980759; called by muse, mutect2
- AHNAK | c.13104C>G p.L4368= | Silent (SNP) | VAF 56/270 reads (21%) | catalogued as COSV57213102, COSV57227275; called by muse, mutect2, varscan2
- AK7 | c.783G>C p.V261= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV50880995; called by muse, mutect2, varscan2
- ANKRD13A | c.828G>A p.V276= | Silent (SNP) | VAF 63/193 reads (33%) | catalogued as COSV55678039; called by muse, mutect2, varscan2
- AP1M2 | c.573G>A p.L191= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1568432510, COSV51569161; called by muse, mutect2, varscan2
- AP3D1 | c.1992G>A p.E664= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV61432219; called by muse, mutect2, varscan2
- ARL4D | c.429G>A p.L143= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV60721383; called by muse, mutect2, varscan2
- ARSL | c.93C>T p.S31= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs779081651, COSV66965081; called by muse, mutect2, varscan2
- ATG2B | c.888C>T p.L296= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV63425068; called by muse, mutect2, varscan2
- AZI2 | c.126C>T p.V42= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs1419907710, COSV55425238; called by muse, mutect2, varscan2
- BAG6 | c.2559C>T p.I853= (on ENST00000676571; = p.I806= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as COSV52994407; called by muse, varscan2
- BPIFA2 | c.264C>T p.V88= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV53612011; called by muse, mutect2, varscan2
- BSPRY | c.756G>A p.L252= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV53058070; called by muse, mutect2, varscan2
- CBLB | c.1314C>T p.I438= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV51435213; called by muse, mutect2, varscan2
- CCDC66 | c.1524G>A p.Q508= (on ENST00000394672 / NM_001353147.1; = p.Q474= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV58308567; called by muse, mutect2, varscan2
- CCDC86 | c.708G>A p.P236= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs752289054, COSV57124655, COSV99920261; called by muse, mutect2, varscan2
- CCR7 | c.582C>G p.L194= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV55850369; called by muse, mutect2, varscan2
- CHD4 | c.4830G>C p.V1610= (on ENST00000357008 / NM_001363606.2; = p.V1623= on NM_001273.5) | Silent (SNP) | VAF 112/527 reads (21%) | catalogued as COSV58909146; called by muse, mutect2, varscan2
- CHST6 | c.885C>T p.L295= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1375435270, COSV60001507; called by muse, mutect2, varscan2
- COL2A1 | c.3807C>T p.I1269= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV61533559; called by muse, mutect2, varscan2
- CORO7 | c.1485C>T p.L495= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs775535940, COSV52033426; called by muse, mutect2, varscan2
- CREB3 | c.1011C>G p.L337= | Silent (SNP) | VAF 59/372 reads (16%) | catalogued as COSV59211084; called by muse, mutect2
- CTCF | c.1602G>A p.Q534= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs1487140145, COSV50506930; called by muse, mutect2, varscan2
- CTNNAL1 | c.924G>A p.E308= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1199727544, COSV57701622, COSV57705162; called by muse, mutect2, varscan2
- CTNNBL1 | c.1419C>T p.I473= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1288226745, COSV63746927; called by muse, mutect2, varscan2
- DCP1A | c.1068G>A p.L356= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, varscan2
- DHX58 | c.699G>A p.L233= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV52427921; called by muse, mutect2, varscan2
- DLGAP1 | c.2523C>G p.L841= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV59830598; called by muse, mutect2, varscan2
- DNAH8 | c.12438C>T p.F4146= | Silent (SNP) | VAF 38/203 reads (19%) | catalogued as COSV59475316; called by muse, mutect2, varscan2
- DNAJB11 | c.501G>A p.R167= | Silent (SNP) | VAF 27/207 reads (13%) | catalogued as COSV54003563; called by muse, mutect2, varscan2
- DOLK | c.147C>G p.L49= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs1554826858, COSV101001512, COSV65364433; ClinVar: likely benign; called by muse, mutect2, varscan2
- EDRF1 | c.2064G>A p.L688= (on ENST00000356792 / NM_001202438.2; = p.L654= on NM_015608.2) | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs747365230, COSV61765928; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2598C>T p.F866= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as rs777227392, COSV62569296; called by muse, mutect2, varscan2
- EIF5B | c.3117G>C p.V1039= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV56816298; called by muse, mutect2, varscan2
- ELFN2 | c.1302C>T p.V434= | Silent (SNP) | VAF 71/293 reads (24%) | catalogued as COSV68746277; called by muse, mutect2, varscan2
- EMILIN2 | c.2229G>A p.Q743= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs200645018, COSV54426839; called by muse, mutect2, varscan2
- ERCC6L2 | c.1692C>G p.L564= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs760353466, COSV56633766; called by muse, mutect2, varscan2
- F2RL3 | c.666C>T p.R222= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV50186431; called by muse, mutect2, varscan2
- FAM89B | c.569G>A p.*190= (on ENST00000530349 / NM_001098785.2; = p.*177= on NM_152832.3) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV57079247; called by muse, varscan2
- FAT4 | c.9726C>G p.L3242= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs1384860308, COSV58683366, COSV58704426; called by muse, mutect2, varscan2
- FLNA | c.7701G>A p.L2567= (on ENST00000369850 / NM_001110556.2; = p.L2559= on NM_001456.3) | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV61049983; called by muse, mutect2, varscan2
- FOXRED1 | c.16C>T p.L6= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs202093490, COSV55008657; called by muse, varscan2
- GANC | c.81C>T p.I27= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GDAP1 | c.105C>T p.F35= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55187007; called by muse, mutect2, varscan2
- GLRA1 | c.756G>C p.L252= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV51010381; called by muse, mutect2, varscan2
- GLRA4 | c.804C>G p.L268= | Silent (SNP) | VAF 72/345 reads (21%) | catalogued as COSV65456836; called by muse, mutect2, varscan2
- GLS2 | c.984C>G p.L328= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as rs770208605; called by muse, mutect2, varscan2
- GPR84 | c.1014C>T p.L338= | Silent (SNP) | VAF 65/241 reads (27%) | catalogued as COSV57210355; called by muse, mutect2, varscan2
- GTSE1 | c.72G>A p.K24= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as COSV66844975; called by muse, mutect2, varscan2
- GYPC | c.386G>A p.*129= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2
- HMCES | c.1023G>A p.E341= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV101077392; called by muse, mutect2
- HTT | c.5784C>T p.I1928= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as COSV61868102; called by muse, mutect2, varscan2
- HUWE1 | c.7659G>A p.L2553= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- INF2 | c.2346C>T p.I782= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- INTS13 | c.1644G>A p.E548= | Silent (SNP) | VAF 132/551 reads (24%) | catalogued as COSV53905041; called by muse, mutect2, varscan2
- IRF2BPL | c.1881C>G p.L627= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53148683; called by muse, mutect2, varscan2
- IRS1 | c.576C>T p.I192= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs1016697016, COSV59339402; called by muse, mutect2, varscan2
- IRS1 | c.330C>G p.L110= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV59339411; called by muse, mutect2, varscan2
- ITGB1 | c.1596C>T p.V532= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV56486225; called by muse, mutect2, varscan2
- ITGB1 | c.33G>A p.L11= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV56486254; called by muse, mutect2, varscan2
- ITIH6 | c.3141G>A p.E1047= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV54493709; called by muse, mutect2, varscan2
- KCNA1 | c.384G>A p.E128= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV66838516; called by muse, mutect2, varscan2
- KCNJ5 | c.687C>T p.I229= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as rs149327599; called by muse, mutect2, varscan2
- KCNS2 | c.252C>T p.F84= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV54640795; called by muse, varscan2
- KCNT1 | c.2397C>T p.I799= (on ENST00000488444; = p.I818= on NM_020822.3) | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs149452823; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM2B | c.2244C>G p.L748= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV65644435; called by muse, mutect2, varscan2
- KIF1B | c.2349G>A p.L783= (on ENST00000377086 / NM_001365952.1; = p.L737= on NM_015074.3) | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs1328595743, COSV55814974; called by muse, mutect2, varscan2
- KIF1C | c.520C>T p.L174= | Silent (SNP) | VAF 47/231 reads (20%) | catalogued as COSV57906800; called by muse, mutect2, varscan2
- KIF1C | c.2499C>G p.L833= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100297086, COSV57906812; called by muse, mutect2, varscan2
- KLHL41 | c.876G>A p.L292= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV52931453; called by muse, mutect2, varscan2
- KRR1 | c.282G>A p.L94= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV56992434; called by muse, mutect2, varscan2
- LAMA1 | c.2604G>A p.G868= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs200170562, COSV67533691, COSV67543344; called by muse, mutect2, varscan2
- LAMC2 | c.993G>A p.L331= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as COSV51459156; called by muse, mutect2, varscan2
- LILRB3 | c.126G>A p.G42= | Silent (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- LIPI | c.273C>T p.F91= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs1484310793, COSV60708200; called by muse, mutect2, varscan2
- LRP2 | c.5241C>T p.F1747= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV55570214; called by muse, mutect2, varscan2
- MAGEA10 | c.438C>G p.L146= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as COSV54883212; called by muse, mutect2, varscan2
- MAP1B | c.2655C>T p.T885= | Silent (SNP) | VAF 56/266 reads (21%) | catalogued as COSV57104983; called by muse, mutect2, varscan2
- MARCHF2 | c.648G>A p.L216= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV53106511; called by muse, mutect2, varscan2
- MARCHF6 | c.1218G>C p.L406= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV56886287; called by muse, mutect2, varscan2
- MED14 | c.1203G>C p.L401= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs771003733, COSV61358323; called by muse, mutect2, varscan2
- MROH7 | c.1458G>C p.L486= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59876942; called by muse, mutect2, varscan2
- MRPS2 | c.744C>G p.L248= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV54094117; called by muse, mutect2, varscan2
- MSH5 | c.360G>A p.Q120= | Silent (SNP) | VAF 87/201 reads (43%) | catalogued as COSV65211175; called by muse, mutect2, varscan2
- MSRB2 | c.390G>A p.L130= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV64737991; called by muse, mutect2, varscan2
- MUC16 | c.40788C>T p.F13596= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV66689962; called by muse, mutect2, varscan2
- MUC17 | c.12984C>T p.F4328= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs572357520, COSV60281580; called by muse, mutect2, varscan2
- MYOC | c.492G>A p.E164= | Silent (SNP) | VAF 114/586 reads (19%) | catalogued as COSV50677853; called by muse, mutect2, varscan2
- NAIF1 | c.54G>A p.E18= | Silent (SNP) | VAF 76/346 reads (22%) | catalogued as COSV66092230; called by muse, varscan2
- NIN | c.5949G>A p.Q1983= (on ENST00000382041 / NM_182946.1; = p.Q1270= on NM_016350.4) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55403851; called by muse, mutect2, varscan2
- NIN | c.5718G>A p.L1906= (on ENST00000382041 / NM_182946.1; = p.L1193= on NM_016350.4) | Silent (SNP) | VAF 47/200 reads (24%) | catalogued as COSV55403884; called by muse, mutect2, varscan2
- NUP160 | c.897C>T p.I299= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as rs963421077, COSV65855725; called by muse, mutect2, varscan2
- NUP210 | c.2775C>G p.L925= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs773463749, COSV54412737; called by muse, mutect2, varscan2
- OR5AK2 | c.663C>T p.I221= | Silent (SNP) | VAF 57/264 reads (22%) | catalogued as rs1433966355, COSV58804143; called by muse, mutect2, varscan2
- OR8B8 | c.84C>T p.F28= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV60143662; called by muse, mutect2, varscan2
- PADI2 | c.1974C>T p.F658= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV64954680; called by muse, varscan2
- PADI2 | c.1893C>T p.F631= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as COSV64954687; called by muse, varscan2
- PADI3 | c.78C>A p.L26= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV64935210, COSV64935259; called by muse, mutect2, varscan2
- PEX26 | c.435C>T p.L145= | Silent (SNP) | VAF 49/243 reads (20%) | catalogued as COSV61605181; called by muse, mutect2, varscan2
- PHKA2 | c.2385C>G p.L795= | Silent (SNP) | VAF 77/444 reads (17%) | catalogued as rs777278113, COSV66055860; called by muse, mutect2, varscan2
- PIWIL1 | c.285G>A p.Q95= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV55351063; called by muse, mutect2, varscan2
- PKD1 | c.5727C>T p.I1909= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1406576394, COSV51924257; called by muse, mutect2, varscan2
- PKHD1 | c.960C>T p.L320= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV61891667; called by muse, mutect2, varscan2
- PLCG2 | c.1293G>A p.T431= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs991961039, COSV63867757; called by muse, mutect2, varscan2
- PLEKHA1 | c.117C>T p.F39= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs142005373; called by muse, mutect2, varscan2
- PLXNB2 | c.2796C>T p.L932= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV63784005; called by muse, mutect2, varscan2
- PLXNB3 | c.4014G>A p.E1338= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs781800524, COSV62801386; called by muse, mutect2, varscan2
- PLXND1 | c.4575C>T p.I1525= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs865925326, COSV60718871; called by muse, mutect2, varscan2
- POTEA | c.1422C>G p.L474= (on ENST00000519951 / NM_001005365.2; = p.L428= on NM_001002920.1) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs200028382; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.885G>A p.V295= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV53455266; called by muse, mutect2, varscan2
- PPIP5K1 | c.864G>A p.G288= | Silent (SNP) | VAF 53/350 reads (15%) | catalogued as COSV58477437; called by muse, mutect2, varscan2
- PPL | c.4911G>A p.Q1637= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV52172248; called by muse, mutect2, varscan2
- PPP1R12C | c.939G>T p.R313= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV54739866; called by muse, mutect2, varscan2
- PPP1R15B | c.780G>T p.L260= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as COSV65815464, COSV65816465; called by muse, mutect2, varscan2
- PRELP | c.954C>G p.L318= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV58117361, COSV58117841; called by muse, mutect2, varscan2
- PTGIS | c.891C>G p.L297= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV54840088; called by muse, mutect2, varscan2
- PTK7 | c.2706C>T p.L902= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs779866455, COSV57851078; called by muse, mutect2, varscan2
- RBM17 | c.171G>A p.L57= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV65914798; called by muse, mutect2, varscan2
- RFT1 | c.243G>A p.Q81= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV56250074; called by muse, mutect2, varscan2
- RIBC2 | c.564C>T p.L188= | Silent (SNP) | VAF 72/316 reads (23%) | catalogued as COSV61582183; called by muse, varscan2
- RNF213 | c.13557G>A p.P4519= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as rs766162624, COSV60407175; called by muse, mutect2, varscan2
- RPL26L1 | c.57C>T p.F19= | Silent (SNP) | VAF 55/295 reads (19%) | catalogued as COSV54200258; called by muse, mutect2, varscan2
- RREB1 | c.3072C>T p.V1024= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV58563939; called by muse, mutect2, varscan2
- RTL9 | c.1332C>G p.V444= | Silent (SNP) | VAF 69/351 reads (20%) | catalogued as COSV71826212; called by muse, mutect2, varscan2
- RYR1 | c.9795G>A p.E3265= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV62108465; called by muse, mutect2, varscan2
- RYR1 | c.13674G>A p.R4558= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as COSV62108474; called by muse, mutect2, varscan2
- SBNO2 | c.2730C>T p.L910= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SEC24B | c.2467C>T p.L823= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV54505287; called by muse, mutect2, varscan2
- SGPP2 | c.615C>T p.L205= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV58331231; called by muse, mutect2, varscan2
- SKAP1 | c.972G>C p.L324= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV61145172; called by muse, mutect2
- SLC12A7 | c.2574C>G p.L858= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- SLC16A6 | c.369C>T p.I123= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV59179181; called by muse, mutect2
- SLC29A3 | c.1254C>T p.L418= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as COSV64386029; called by muse, mutect2, varscan2
- SLC30A5 | c.1239G>A p.E413= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV67450356; called by muse, mutect2, varscan2
- SLC6A19 | c.1587C>T p.F529= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1443232351, COSV57253966; called by muse, mutect2, varscan2
- SLC9A4 | c.813C>T p.I271= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs762160178, COSV54829359, COSV54838298; called by muse, mutect2, varscan2
- SND1 | c.1956G>A p.Q652= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- SNRNP200 | c.3522C>T p.I1174= | Silent (SNP) | VAF 60/230 reads (26%) | catalogued as COSV60493844; called by muse, mutect2, varscan2
- SPACA3 | c.13C>T p.L5= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52192440; called by muse, mutect2, varscan2
- SPG21 | c.909C>T p.I303= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as rs367966974; called by muse, mutect2, varscan2
- SPTBN2 | c.4800G>A p.A1600= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs146007976; called by muse, mutect2, varscan2
- SPX | c.99G>A p.E33= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV57021651; called by muse, varscan2
- SYT5 | c.186G>A p.K62= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV54749199; called by muse, mutect2
- SZT2 | c.3972G>A p.L1324= (on ENST00000634258 / NM_001365999.1; = p.L1267= on NM_015284.4) | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs1444974427, COSV65173724; called by muse, mutect2, varscan2
- TBC1D10C | c.339G>A p.K113= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs768127771, COSV56704906; called by muse, mutect2, varscan2
- TCF21 | c.207G>A p.L69= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52819481; called by muse, mutect2
- TEP1 | c.6756C>T p.L2252= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs751449109, COSV52998752; called by muse, mutect2, varscan2
- THBS3 | c.951C>T p.I317= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV64250675; called by muse, mutect2, varscan2
- TK1 | c.507G>A p.E169= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs746775840, COSV56746526; called by muse, mutect2
- TPP2 | c.2400G>A p.V800= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV65754527; called by muse, mutect2, varscan2
- TRIP12 | c.4150C>T p.L1384= | Silent (SNP) | VAF 65/288 reads (23%) | catalogued as COSV52269056, COSV52271264; called by muse, mutect2, varscan2
- TRMT11 | c.639G>A p.V213= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV57674114; called by muse, mutect2, varscan2
- TRO | c.3423T>C p.G1141= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV51506779; called by muse, mutect2, varscan2
- TRPV3 | c.99G>A p.E33= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV56794949; called by muse, mutect2, varscan2
- TTLL5 | c.2946C>T p.I982= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV54042731; called by muse, varscan2
- UBP1 | c.300G>C p.R100= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV52147511; called by muse, mutect2, varscan2
- UQCRC1 | c.660C>T p.L220= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV52552839, COSV99178961; called by muse, mutect2, varscan2
- USP33 | c.2616T>C p.P872= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as COSV62471175; called by muse, mutect2, varscan2
- VPS39 | c.1137G>A p.V379= (on ENST00000348544 / NM_001301138.2; = p.V368= on NM_015289.5) | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV58792692; called by muse, mutect2, varscan2
- WDR72 | c.2094C>G p.L698= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV64752782; called by muse, mutect2
- ZBTB11 | c.639C>T p.F213= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as rs773261825, COSV57244061; called by muse, mutect2, varscan2
- ZER1 | c.72C>T p.T24= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV52568226; called by muse, mutect2, varscan2
- ZNF324 | c.1068C>G p.L356= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- ZNF408 | c.1794C>G p.L598= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1245439329, COSV61239132; called by muse, mutect2, varscan2
- ZNF655 | c.654G>A p.G218= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53159899; called by muse, varscan2
- AC024598.1 | c.1130-1003G>A | Intron (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60824690; called by muse, mutect2, varscan2
- ALG3 | chr3:184249256 C>G | 5'Flank (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61081024; called by muse, varscan2
- AP000769.3 | chr11:65501609 G>A | 5'Flank (SNP) | VAF 34/116 reads (29%) | catalogued as rs755034100; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501707 G>A | 5'Flank (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502231 G>C | 5'Flank (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502443 G>C | 5'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503624 G>C | 5'Flank (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503923 G>C | 5'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505373 G>C | 5'Flank (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- BAX | c.474+185C>G | Intron (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99508937; called by muse, mutect2
- EP400 | c.5755-604G>C | Intron (SNP) | VAF 36/173 reads (21%) | catalogued as COSV100202275; called by muse, mutect2, varscan2
- IL36B | c.261+900C>G | Intron (SNP) | VAF 11/152 reads (7%) | catalogued as COSV52088537; called by muse, mutect2
- MIR205 | n.94G>C | RNA (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MIR520A | n.43G>C | RNA (SNP) | VAF 51/247 reads (21%) | called by muse, mutect2, varscan2
- NFRKB | c.-6G>A | 5'UTR (SNP) | VAF 51/231 reads (22%) | catalogued as COSV58760128; called by muse, mutect2, varscan2
- PRR12 | c.52-381G>A | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SAT1 | c.*2G>C | 3'UTR (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100803912; called by muse, mutect2
- SCRIB | c.643-16C>G | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as COSV57584154; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20147G>C | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101043942, COSV67448551; called by muse, mutect2, varscan2
- XIRP2 | c.-76G>C | 5'UTR (SNP) | VAF 22/96 reads (23%) | catalogued as COSV54729195; called by muse, mutect2, varscan2
